Gene-level copy-number profile of tumor specimen C3L-06706-02 from CPTAC case C3L-06706, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.2 years (16,868 days).
Specimen C3L-06706-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3db8c5ed-aed9-4e8e-b37f-8508c6b0aa31.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06706-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/4c27d3bb-6923-4aec-9fdc-65693e78f2ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 4,206; copy number 2: 45,685; copy number 3: 5,438; copy number 4: 3,495; copy number 5: 80.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,734,895–60,735,715, 1 gene, copy number 5: ATP1B3P1.
- chr9:70,529,060–73,873,297, 36 genes, copy number 5: TRPM3, RN7SL726P, AL159990.2, AL159990.1, MIR204, PIGUP1, RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.1, AL512594.1, RNA5SP286, AL513124.1.
- chr9:74,946,583–78,330,093, 43 genes, copy number 5: C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1, Y_RNA, RNU6-1228P, AL158073.1, AL353780.1, OTX2P1, PCSK5, RBM22P5, RFK, RPSAP9, GCNT1, H3P32, PPIAP87, PRUNE2, PCA3, AL359314.1, AL390239.1, DNAJB5P1, LYPLA2P3, AL353637.1, FOXB2, ATP5MFP3, RFC5P1, VPS13A-AS1, VPS13A, GNA14, GNA14-AS1, NUTF2P3, RNU6-1303P, GNAQ, AL353705.2, RN7SKP59, ASS1P3, AL353705.1, AL353705.3, CEP78, PSAT1.

Autosomal genes at a single copy (total copy number 1): 1,350. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
